TCGA case TCGA-3P-A9WA — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Greenville Health System. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e35b2813-427e-4e83-95f6-4f0281f42a59

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (2)
1. Cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8440/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.3 years (20,211 days); Year of diagnosis: 2013; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: RX; Days to last follow up: 420 days (1.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 92 days; Days to treatment end: 212 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Uterus, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 55.3 years (20,215 days); Days to diagnosis: 4 days; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 54 days; Treatment anatomic sites: Uterus.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 243 days; Disease response: Tumor Free.
- Days to follow up: 420 days (1.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3P-A9WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 660 mg.
  Slide TCGA-3P-A9WA-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3P-A9WA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3P-A9WA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Anatomic organ subdivision: Left; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Dilatation and Curettage, Polypectomy; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 2: Pharmaceutical therapy drug name: Paraplatin.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Uterus; Other malignancy histological type: Intraepithelial Serous Carcinoma; Days from index date to other malignancy diagnosis: 4.
- Other malignancy form, Surgery: Other malignancy surgery type: Hysterectomy.
- Other malignancy form, Other malignancy staging: AJCC pathologic tumor stage: Stage II.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 420 days; disease-specific survival: no event (censored), 420 days; disease-free interval: no event (censored), 420 days; progression-free interval: no event (censored), 420 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3P-A9WA-01A-11D-A402-01): tumor purity 0.85, ploidy 3.5, whole-genome doublings 1.
